Gene-level copy-number profile of tumor specimen MP2PRT-PAUNHM-TMP1-A from MP2PRT case MP2PRT-PAUNHM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.0 years (1,820 days).
Specimen MP2PRT-PAUNHM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b2c7d0b5-b509-4721-bdf3-d6340de619d6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAUNHM-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,404 have no estimate.
https://portal.gdc.cancer.gov/files/7cd82e21-9a61-473f-8c24-1b174375f2b2

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 71; copy number 2: 928; copy number 3: 2,429; copy number 4: 54,049; copy number 6: 722.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,256,337–38,311,808, 9 genes (within-gene range 0–1): TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1.
- chr7:142,618,849–142,667,718, 7 genes: TRBV19, TRBV20-1, TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6.
- chr14:22,438,547–22,450,139, 4 genes (within-gene range 0–4): TRDD1, TRDD2, TRDD3, TRDJ1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 71. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
